Gene-level copy-number profile of tumor specimen AP-CT3G-2G from APOLLO case AP-CT3G, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2.
Specimen AP-CT3G-2G: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 63beb502-80ef-496e-9c90-6b757eb66f20.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-CT3G-FW (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/bb2026aa-ff05-40f0-8f61-a9a3d2e709a1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 209; copy number 1: 843; copy number 2: 6,473; copy number 3: 20,907; copy number 4: 13,652; copy number 5: 9,825; copy number 6: 3,256; copy number 7: 507; copy number 8: 583; copy number 9: 1,841; copy number 10: 282; copy number 11: 20.

Homozygous deletions (total copy number 0; autosomes only): 209 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–545,781, 19 genes: AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.
- chr8:737,628–1,708,476, 1 gene (within-gene range 0–1): DLGAP2.
- chr8:1,246,789–6,257,537, 49 genes: AC110288.1, AF067845.2, AF067845.1, DLGAP2-AS1, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, RN7SKP159, AC079054.1, AC009435.1.
- chr8:12,064,389–12,177,550, 10 genes (within-gene range 0–1): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr8:12,628,476–14,023,422, 28 genes: RPS3AP35, AC068587.3, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1.
- chr8:14,309,033–14,332,663, 3 genes (within-gene range 0–2): EIF4EP5, RNU7-153P, Y_RNA.
- chr9:19,507,452–23,956,444, 85 genes (broad region; genes not listed).
- chr17:36,165,681–36,439,566, 14 genes (within-gene range 0–3): TBC1D3B, AC243829.1, CCL3L3, CCL4L2, AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G, TBC1D3H, RNU6-1192P, TBC1D3F.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,229 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:117,544,205–117,544,311, 1 gene, copy number 8: RNU6-1200P.
- chr3:162,601,627–162,601,792, 1 gene, copy number 9: AC128716.1.
- chr3:166,160,021–166,721,610, 11 genes, copy number 7: MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1.
- chr6:25,652,201–40,387,590, 734 genes, copy number 7–10 (broad region; genes not listed).
- chr7:37,032–4,883,716, 95 genes, copy number 10 (broad region; genes not listed).
- chr7:8,113,184–50,262,994, 659 genes, copy number 9–11 (broad region; genes not listed).
- chr7:50,304,068–57,837,046, 180 genes, copy number 9–10 (broad region; genes not listed).
- chr7:63,011,463–63,088,261, 4 genes, copy number 9: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3.
- chr7:65,751,142–84,984,506, 325 genes, copy number 7–9 (broad region; genes not listed).
- chr7:86,876,906–94,077,157, 108 genes, copy number 9–10 (broad region; genes not listed).
- chr7:94,495,299–112,896,625, 403 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr7:117,287,120–117,715,971, 1 gene, copy number 9 (within-gene range 4–9): CFTR.
- chr7:117,439,982–125,482,966, 88 genes, copy number 9–10 (broad region; genes not listed).
- chr7:131,493,964–138,589,996, 99 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:141,074,064–143,604,839, 162 genes, copy number 8 (broad region; genes not listed).
- chr7:148,438,309–159,233,377, 231 genes, copy number 7–9 (broad region; genes not listed).
- chr8:122,414,332–123,290,503, 27 genes, copy number 8–10: SMILR, LINC01151, AC108136.1, AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1.
- chr8:133,946,677–133,963,259, 2 genes, copy number 10: AC110741.3, AC110741.2.
- chr14:28,264,390–30,620,064, 34 genes, copy number 7: BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3.
- chr14:67,819,779–68,730,218, 10 genes, copy number 7 (within-gene range 6–7): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1.
- chr14:68,693,656–68,695,734, 1 gene, copy number 7: AL133313.1.
- chr14:93,718,298–93,788,485, 1 gene, copy number 8: PRIMA1.
- chr19:29,923,644–30,038,181, 5 genes, copy number 8: URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr19:34,428,352–35,066,571, 34 genes, copy number 7 (within-gene range 5–7): UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1, ZNF30, AC008555.6, ZNF792, GRAMD1A, AC020907.3, AC020907.4, SCN1B, HPN.
- chr21:15,928,296–16,645,467, 1 gene, copy number 7 (within-gene range 5–7): MIR99AHG.
- chr21:16,121,310–16,815,688, 12 genes, copy number 7: RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1.

Autosomal genes at a single copy (total copy number 1): 843. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
